Somatic mutation profile of tumor specimen HCM-CSHL-0860-C18-06A (aliquot HCM-CSHL-0860-C18-06A-11D-A881-36) from HCMI case HCM-CSHL-0860-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 70.3 years (25,687 days).
Specimen HCM-CSHL-0860-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85d9d1ec-4de6-45e2-ad7f-21061ebca52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0860-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0860-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64bd9214-8f62-4a3a-96f3-f4b488deb241

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Nonsense Mutation 4, RNA 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 132/339 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ACKR4 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs746421374; called by muse, mutect2, varscan2
- AFF3 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs868486028, COSV57866119; called by muse, mutect2, varscan2
- ARHGEF37 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 167/568 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as rs528783472; called by muse, varscan2
- COL25A1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 402/656 reads (61%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1233681099, COSV101211297; called by muse, varscan2
- DSCAML1 | c.4070G>T p.G1357V (on ENST00000321322; = p.G1297V on NM_020693.4) | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV100355025; called by muse, varscan2
- DSCAML1 | c.4069G>T p.G1357C (on ENST00000321322; = p.G1297C on NM_020693.4) | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751431959; called by muse, varscan2
- HECTD2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 171/427 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs201433936; called by muse, mutect2, varscan2
- HS3ST2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 232/509 reads (46%) | catalogued as rs1319192100, COSV54462447; called by muse, varscan2
- IKZF2 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1375506817; called by muse, mutect2, varscan2
- KCNG3 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 55/1027 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1283500670; called by muse, mutect2
- KMT2A | c.2929G>A p.G977S | Missense Mutation (SNP) | VAF 28/537 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs782439084, COSV100630302; called by muse, mutect2
- MARCHF11 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 31/735 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921889840, COSV100198278, COSV60126013, COSV60127080; called by muse, mutect2
- MUC5B | c.3431C>A p.S1144Y | Missense Mutation (SNP) | VAF 215/540 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs2672801; called by muse, mutect2, varscan2
- NOTCH1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 164/405 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs756642176, COSV53041965; ClinVar: uncertain significance; called by muse, varscan2
- RIMBP2 | c.453+1G>A p.X151_splice | Splice Site (SNP) | VAF 161/386 reads (42%) | catalogued as rs1451846888; called by muse, mutect2, varscan2
- SLC8A1 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV60499309; called by muse, mutect2
- SNAP25 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 127/489 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs374115269; called by muse, mutect2, varscan2
- ZNF471 | c.1637A>G p.N546S | Missense Mutation (SNP) | VAF 17/514 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as rs1224568002; called by muse, mutect2
- ABCA13 | c.11477C>A p.S3826* | Nonsense Mutation (SNP) | VAF 64/296 reads (22%) | called by muse, varscan2
- ASMTL | c.212A>T p.N71I | Missense Mutation (SNP) | VAF 159/503 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.222); called by muse, varscan2
- CTR9 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAH11 | c.5653C>A p.L1885I | Missense Mutation (SNP) | VAF 136/466 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ELAPOR2 | c.3036A>T p.K1012N (on ENST00000450689 / NM_001142749.3; = p.K845N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM200B | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 107/190 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIAA1549 | c.2340G>T p.L780F | Missense Mutation (SNP) | VAF 73/975 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.114); called by muse, mutect2
- MUC16 | c.29627C>G p.T9876S | Missense Mutation (SNP) | VAF 129/543 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NR3C1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 35/792 reads (4%) | called by muse, mutect2
- OR51A7 | c.893T>A p.I298N | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDE2A | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 145/361 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIWIL1 | c.1972T>G p.W658G | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCE | c.517A>C p.M173L | Missense Mutation (SNP) | VAF 26/726 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- SRP68 | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 122/447 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD15 | c.4711T>A p.S1571T | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TLL2 | c.1958C>A p.P653H | Missense Mutation (SNP) | VAF 28/561 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF649 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 18/377 reads (5%) | called by muse, mutect2
- ABCD1 | c.1680G>A p.P560= | Silent (SNP) | VAF 196/512 reads (38%) | catalogued as rs782005164, COSV99497643; called by muse, mutect2, varscan2
- ANKFN1 | c.3705T>G p.P1235= (on ENST00000653862; = p.P1088= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 210/1047 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.2139C>T p.N713= (on ENST00000297405 / NM_001363185.1; = p.N609= on NM_052900.3) | Silent (SNP) | VAF 88/260 reads (34%) | catalogued as COSV52099863; called by muse, mutect2, varscan2
- KCND1 | c.1626C>T p.I542= | Silent (SNP) | VAF 46/770 reads (6%) | catalogued as rs782697027; called by muse, mutect2
- NPSR1 | c.1056G>A p.T352= | Silent (SNP) | VAF 120/374 reads (32%) | catalogued as rs143448171; called by muse, mutect2, varscan2
- PGAP1 | c.2598T>A p.L866= | Silent (SNP) | VAF 90/232 reads (39%) | called by muse, varscan2
- PHIP | c.2034C>T p.T678= | Silent (SNP) | VAF 147/336 reads (44%) | called by muse, mutect2, varscan2
- LINC00662 | n.633T>G | RNA (SNP) | VAF 183/677 reads (27%) | called by muse, mutect2, varscan2
- Z97205.1 | n.384A>G | RNA (SNP) | VAF 25/480 reads (5%) | called by muse, mutect2
- ZFX | c.58+805_58+816del | Intron (DEL) | VAF 106/270 reads (39%) | called by mutect2, pindel, varscan2
